Somatic mutation profile of tumor specimen 0DI5FK from CCDI case PBBUXZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,922 days).
Specimen 0DI5FK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 572848f3-0dd9-4f54-ab39-aa73c01d8492.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI5EE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06069523-ec45-4f62-8175-d8946c3a7b16

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, 5'Flank 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 366/1366 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.782+1G>A p.X261_splice | Splice Site (SNP) | VAF 250/390 reads (64%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CDKN2B | c.5G>C p.R2P | Missense Mutation (SNP) | VAF 92/688 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV52805098; called by muse, varscan2
- MAGEL2 | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 478/985 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1455591080; called by muse, varscan2
- MUC5B | c.6170C>T p.T2057M | Missense Mutation (SNP) | VAF 186/1291 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201461460; called by muse, varscan2
- ZNF16 | c.1400G>C p.G467A | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52764628; called by muse, varscan2
- MPHOSPH9 | c.1308T>A p.N436K | Missense Mutation (SNP) | VAF 135/1071 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.476); called by muse, varscan2
- NCAPD3 | c.4421C>T p.S1474F | Missense Mutation (SNP) | VAF 186/674 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- NCAPD3 | c.4373C>G p.S1458* | Nonsense Mutation (SNP) | VAF 169/672 reads (25%) | called by muse, varscan2
- OR5M1 | c.469T>C p.F157L | Missense Mutation (SNP) | VAF 240/1319 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ZNF16 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 110/532 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.343); called by muse, varscan2
- ARHGAP27 | c.897G>A p.V299= | Silent (SNP) | VAF 400/920 reads (43%) | called by muse, varscan2
- PEAR1 | c.1839C>T p.G613= | Silent (SNP) | VAF 66/530 reads (12%) | called by muse, varscan2
- WWC1 | c.822G>A p.P274= | Silent (SNP) | VAF 180/1179 reads (15%) | catalogued as rs1356011702; called by muse, varscan2
- BTBD1 | c.863-51A>C | Intron (SNP) | VAF 38/292 reads (13%) | called by muse, varscan2
- PERM1 | chr1:981152 G>A | 5'Flank (SNP) | VAF 84/828 reads (10%) | catalogued as rs373197642; called by muse, varscan2
- SCP2 | c.1549-42A>G | Intron (SNP) | VAF 124/702 reads (18%) | called by muse, varscan2
